Gene-level copy-number profile of tumor specimen TCGA-91-8496-01A from TCGA case TCGA-91-8496, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.0 years (23,358 days).
Specimen TCGA-91-8496-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e28ac114-fe79-4ef9-aeb3-c0f6c1f93f6a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-91-8496-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f700328f-6967-4eee-8897-d75879df3611

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 510; copy number 4: 45,952; copy number 5: 834; copy number 6: 5,527; copy number 7: 2,699; copy number 8: 2,061; copy number 9: 1,493; copy number 10: 431; copy number 11: 15; copy number 12: 105; copy number 13: 184; copy number 14: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-91-8496-01A-11D-2389-01): tumor purity 0.5, ploidy 2.25, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,416 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:51,102,221–51,148,086, 1 gene, copy number 12 (within-gene range 8–12): C1orf185.
- chr1:51,157,788–53,976,031, 104 genes, copy number 12 (broad region; genes not listed).
- chr1:54,756,898–72,979,314, 269 genes, copy number 9 (broad region; genes not listed).
- chr16:11,555–22,916,338, 826 genes, copy number 9–11 (broad region; genes not listed).
- chr16:24,610,209–25,454,647, 22 genes, copy number 10 (within-gene range 7–10): TNRC6A, LINC01567, AC008731.1, SLC5A11, ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT, LINC02191, CYCSP39.
- chr16:25,824,710–25,826,330, 1 gene, copy number 10: AC093524.1.
- chr16:46,469,341–54,158,512, 184 genes, copy number 13 (within-gene range 8–13) (broad region; genes not listed).
- chr16:58,733,910–59,199,395, 1 gene, copy number 14 (within-gene range 8–14): AC106793.1.
- chr16:59,004,213–60,053,973, 8 genes, copy number 14: Metazoa_SRP, RPS27P27, AC092121.1, RNU4-58P, DUXAP11, APOOP5, LINC02141, AC009094.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
